Somatic mutation profile of tumor specimen TARGET-30-PASMPT-01A (aliquot TARGET-30-PASMPT-01A-01D) from TARGET case TARGET-30-PASMPT, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 1.2 years (449 days).
Specimen TARGET-30-PASMPT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1931417b-b2bc-4663-859f-793c57157306.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASMPT-10A (Blood Derived Normal), aliquot TARGET-30-PASMPT-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a5e9d7f1-23e0-4763-8d42-8f57c54db9d8

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC168 | c.9457G>C p.G3153R | Missense Mutation (SNP) | VAF 87/223 reads (39%) | SIFT tolerated (0.86); PolyPhen benign (0.015); catalogued as COSV59426054; called by muse, mutect2, varscan2
- FANCM | c.5230G>A p.E1744K | Missense Mutation (SNP) | VAF 50/158 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.041); catalogued as rs776474104, COSV57506867; called by muse, mutect2, varscan2
- FLNB | c.1279G>A p.V427M | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.594); catalogued as rs764813590, COSV55896363; called by muse, mutect2, varscan2
